Somatic mutation profile of tumor specimen 0DVVL2 from CCDI case PBCNBH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Chordoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,479 days).
Specimen 0DVVL2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea12e6c1-8710-41a6-9ab5-12d73daf2da3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVVMD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9177ba8-de72-4336-aca8-2183c560bf15

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASAP2 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 98/1272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748052568, COSV55633047; called by muse, mutect2
- CDCP1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 49/728 reads (7%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.953); catalogued as rs370503753; called by muse, mutect2
- PLPPR5 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 34/433 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs142171434; called by muse, mutect2
- PLXNB3 | c.3632C>T p.A1211V | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs868946447, COSV62798119; called by muse, mutect2, varscan2
- AIG1 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 70/638 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERAP2 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 100/1216 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.024); called by muse, mutect2
- HIVEP2 | c.4501G>A p.A1501T | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- KIF6 | c.177-1G>A p.X59_splice | Splice Site (SNP) | VAF 50/674 reads (7%) | called by muse, mutect2
- MTOR | c.6836C>T p.T2279I | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRIM49 | c.1052G>A p.W351* | Nonsense Mutation (SNP) | VAF 48/1492 reads (3%) | called by muse, mutect2
- TAMALIN | c.549-13T>A | Intron (SNP) | VAF 26/177 reads (15%) | called by muse, mutect2, varscan2
- VSIG8 | c.431-43C>G | Intron (SNP) | VAF 34/336 reads (10%) | called by muse, mutect2
